Somatic mutation profile of tumor specimen MP2PRT-PAPJHP-TBP1-A (aliquot MP2PRT-PAPJHP-TBP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPJHP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (895 days).
Specimen MP2PRT-PAPJHP-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adab8bf4-e47c-4fa1-8fff-7474fbea6aff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJHP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJHP-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0975bfcc-57cb-464f-88d2-11e9f86de180

The open-access MAF lists 426 somatic variants for this specimen: 310 protein-altering or splice-affecting, 102 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 102, Frame Shift Ins 38, Intron 10, Splice Region 5, Nonsense Mutation 2, Frame Shift Del 2, Nonstop Mutation 2, 3'Flank 2, 3'UTR 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXCR4 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 21/217 reads (10%) | catalogued as rs104893624, CM030831, COSV54010080; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JAK1 | c.2729T>C p.L910P | Missense Mutation (SNP) | VAF 66/406 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61090359; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 36/274 reads (13%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- ACTG1 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 27/402 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as rs1555666789; ClinVar: uncertain significance; called by muse, mutect2
- ADAM29 | c.2101del p.S701Vfs*4 | Frame Shift Del (DEL) | VAF 32/246 reads (13%) | catalogued as rs34732497, COSV63661841; called by mutect2, varscan2
- ADCY3 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 246/498 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004579539, COSV53170059; called by muse, mutect2, varscan2
- ADGRA2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 58/422 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754053108, COSV59444629, COSV59447231; called by muse, mutect2, varscan2
- ALG10 | c.981dup p.V328Cfs*18 | Frame Shift Ins (INS) | VAF 31/288 reads (11%) | catalogued as rs768493124; called by mutect2, pindel, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 68/252 reads (27%) | catalogued as rs370637835; called by mutect2, varscan2
- ARHGAP45 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 185/384 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV57429214; called by muse, mutect2, varscan2
- ARSA | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 54/567 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.575); catalogued as rs759295985, COSV53350023, COSV53351024; called by muse, mutect2
- ATP10A | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.102); catalogued as COSV100791058; called by muse, mutect2, varscan2
- BAG6 | c.3107dup p.S1037Lfs*4 (on ENST00000676571; = p.S990Lfs*4 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 87/684 reads (13%) | catalogued as rs750783410; called by mutect2, pindel, varscan2
- BICRA | c.661A>G p.S221G | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs1339994246; called by muse, mutect2
- CACNA1I | c.3377T>C p.L1126P | Missense Mutation (SNP) | VAF 11/301 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV100361957; called by muse, mutect2
- CCDC62 | c.1874A>G p.Q625R | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs1392322022, COSV53437234; called by muse, mutect2, varscan2
- CDK12 | c.4382dup p.T1463Nfs*50 (on ENST00000447079 / NM_016507.4; = p.T1454Nfs*50 on NM_015083.3) | Frame Shift Ins (INS) | VAF 54/394 reads (14%) | catalogued as rs760014508; called by mutect2, varscan2
- CEP250 | c.3184A>G p.M1062V | Missense Mutation (SNP) | VAF 117/216 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs182206786; called by muse, mutect2, varscan2
- CLCN6 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766387120, COSV56741556; called by muse, mutect2, varscan2
- CNOT3 | c.732dup p.S245Qfs*8 | Frame Shift Ins (INS) | VAF 84/322 reads (26%) | catalogued as rs753475896; called by mutect2, varscan2
- EDRF1 | c.396dup p.L133Tfs*26 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | catalogued as rs1194762434; called by mutect2, varscan2
- EIF3L | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); catalogued as COSV67739728; called by muse, mutect2
- EVI2B | c.593dup p.N198Kfs*4 | Frame Shift Ins (INS) | VAF 51/256 reads (20%) | catalogued as rs765136869, COSV58364207; called by mutect2, varscan2
- EXOC5 | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1213682501; called by muse, mutect2, varscan2
- F2 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 36/437 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as rs140404878; called by muse, mutect2
- FAM83H | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 176/622 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs781994898, COSV100567801; called by muse, varscan2
- FAT2 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 154/316 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs756023781; called by muse, mutect2, varscan2
- FAT3 | c.6584T>C p.V2195A | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs754110605; called by muse, mutect2, varscan2
- FGF3 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782272422, COSV61926411; called by muse, mutect2
- FH | c.1385A>G p.H462R | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs1466657268; called by muse, mutect2, varscan2
- FLYWCH1 | c.1820dup p.R608Qfs*54 (on ENST00000253928 / NM_001308068.2; = p.R607Qfs*54 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 31/302 reads (10%) | catalogued as rs748361609; called by mutect2, pindel, varscan2
- FMNL1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.437); catalogued as COSV58959986; called by muse, mutect2, varscan2
- GAK | c.3393G>C p.W1131C | Missense Mutation (SNP) | VAF 74/517 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100033571, COSV99041266; called by muse, mutect2, varscan2
- HEY2 | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100856448; called by muse, mutect2
- IGHV7-81 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs373793076; called by muse, mutect2, varscan2
- IL21R | c.1079dup p.S361Lfs*5 | Frame Shift Ins (INS) | VAF 54/542 reads (10%) | catalogued as rs754481996; called by mutect2, pindel
- JAK1 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV61088550, COSV61093090, COSV61093632; called by muse, mutect2
- KIF18B | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs751146669; called by muse, mutect2, varscan2
- KIT | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 85/445 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV55386801, COSV55412859; called by muse, mutect2, varscan2
- KMT5A | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1370980819; called by muse, mutect2, varscan2
- LAMC3 | c.4097G>A p.S1366N | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1015174669; called by muse, mutect2
- LRPPRC | c.3331A>G p.I1111V | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.277); catalogued as rs781451529, COSV99580112; called by muse, mutect2, varscan2
- MAP7D1 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 155/312 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756880630; called by muse, mutect2, varscan2
- MARK4 | c.1960dup p.R654Pfs*18 (on ENST00000262891 / NM_001199867.2; = p.G681Rfs*100 on NM_031417.4) | Frame Shift Ins (INS) | VAF 48/378 reads (13%) | catalogued as rs1568505994; called by mutect2, pindel, varscan2
- MIA3 | c.4939C>T p.P1647S | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs892163913; called by muse, mutect2, varscan2
- MLPH | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377402911; called by muse, mutect2, varscan2
- MPG | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as rs780392088; called by muse, mutect2, varscan2
- MRPL38 | c.1118A>G p.H373R | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs755555376; called by muse, mutect2
- MTX1 | c.22dup p.R8Pfs*55 | Frame Shift Ins (INS) | VAF 136/294 reads (46%) | catalogued as rs755845788; called by mutect2, varscan2
- MUC16 | c.36274C>T p.R12092W | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); catalogued as rs751199072; called by muse, mutect2, varscan2
- MYCBP2 | c.2954T>C p.L985P (on ENST00000357337; = p.L1023P on NM_015057.5) | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62012367; called by muse, mutect2
- NARS2 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.114); catalogued as rs753555379; called by muse, mutect2
- NDUFV3 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 208/396 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as rs1175013016; called by muse, mutect2, varscan2
- NEU1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 48/531 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs570314472; ClinVar: uncertain significance; called by muse, mutect2
- NR3C1 | c.245T>A p.V82D | Missense Mutation (SNP) | VAF 139/275 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1216951244; called by muse, mutect2, varscan2
- NRROS | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 161/366 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1326793733; called by muse, mutect2, varscan2
- NTSR1 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 148/342 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs765918766; called by muse, mutect2
- NYAP1 | c.220T>C p.C74R | Missense Mutation (SNP) | VAF 20/740 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55720430; called by muse, mutect2
- OPRL1 | c.713T>C p.M238T | Missense Mutation (SNP) | VAF 70/752 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1047974479; called by muse, mutect2
- PAOX | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53373819; called by muse, mutect2
- PCARE | c.2626A>G p.T876A | Missense Mutation (SNP) | VAF 24/431 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV100527547; called by muse, mutect2
- PHYHD1 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58281061; called by muse, mutect2
- PODXL2 | c.1490A>G p.D497G | Missense Mutation (SNP) | VAF 43/457 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377374348; called by muse, mutect2
- POU3F1 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 52/588 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV65949083; called by muse, mutect2
- RB1 | c.219_220dup p.A74Efs*4 | Frame Shift Ins (INS) | VAF 28/220 reads (13%) | catalogued as COSV57297594; called by mutect2, varscan2
- RHOBTB2 | c.1500A>G p.S500= | Splice Region (SNP) | VAF 98/196 reads (50%) | catalogued as rs1435050003; called by muse, mutect2, varscan2
- SDF4 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs1246025074; called by muse, mutect2, varscan2
- SERPINB6 | c.916C>T p.R306C (on ENST00000612421 / NM_001271823.2; = p.R287C on NM_004568.6) | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs778841769, COSV59565999; called by muse, mutect2
- SH3BP2 | c.44T>C p.I15T | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs777574434; called by muse, varscan2
- SLC22A11 | c.949A>G p.M317V | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as COSV100102566; called by muse, mutect2, varscan2
- SLC25A22 | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 181/416 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1264072634; called by muse, mutect2, varscan2
- SLC41A1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs776783815; called by muse, mutect2, varscan2
- SLX4 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 25/397 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs1230371509; called by muse, mutect2
- SMC1B | c.2419A>G p.R807G | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV62528384; called by muse, mutect2
- TMC2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as rs138871219; called by muse, mutect2, varscan2
- TRIOBP | c.6308C>G p.P2103R (on ENST00000644935 / NM_001039141.3; = p.P390R on NM_007032.5) | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as COSV58525758; called by muse, mutect2
- TYK2 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs775200017; called by muse, mutect2, varscan2
- UBE2I | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV57648205; called by muse, mutect2
- ULK1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 60/394 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1043850542, COSV58858806; called by muse, varscan2
- ZBTB14 | c.1085C>A p.A362E | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.823); catalogued as COSV63696428; called by muse, mutect2
- ZBTB46 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.692); catalogued as rs774473549; called by muse, mutect2, varscan2
- ZBTB7C | c.1837T>A p.S613T | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1433444792; called by muse, mutect2, varscan2
- ZC3H18 | c.2406dup p.G803Rfs*21 | Frame Shift Ins (INS) | VAF 197/500 reads (39%) | catalogued as rs750724166; called by mutect2, pindel, varscan2
- ZFP36L2 | c.431dup p.G145Rfs*329 | Frame Shift Ins (INS) | VAF 42/349 reads (12%) | catalogued as rs1558428769; called by mutect2, pindel, varscan2
- ZNF333 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1468413680, COSV52885542; called by muse, mutect2
- ZNF521 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.105); catalogued as rs116142901; called by muse, mutect2
- ZNF667 | c.1628T>C p.I543T | Missense Mutation (SNP) | VAF 193/377 reads (51%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.82); catalogued as rs1238636587; called by muse, mutect2, varscan2
- AAMP | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 15/539 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2
- ABCA9 | c.3064T>C p.Y1022H | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2
- ABRA | c.999dup p.G334Wfs*5 | Frame Shift Ins (INS) | VAF 64/403 reads (16%) | called by mutect2, pindel, varscan2
- AC099489.1 | c.9151T>C p.F3051L | Missense Mutation (SNP) | VAF 39/416 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ACOD1 | c.362G>T p.R121M | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ADGRF1 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- AHDC1 | c.3977T>C p.L1326P | Missense Mutation (SNP) | VAF 175/351 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPK2 | c.4664T>C p.V1555A | Missense Mutation (SNP) | VAF 11/285 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- AMBRA1 | c.1055dup p.E353Gfs*49 (on ENST00000458649 / NM_001367468.1; = p.E263Gfs*49 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 36/338 reads (11%) | called by mutect2, pindel, varscan2
- ANKRD55 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AP002748.5 | c.1753dup p.L585Pfs*10 | Frame Shift Ins (INS) | VAF 33/358 reads (9%) | called by mutect2, pindel
- ARHGEF17 | c.3995T>C p.M1332T | Missense Mutation (SNP) | VAF 115/258 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARRDC5 | c.159A>G p.I53M (on ENST00000381781; = p.I39M on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/311 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ARTN | c.324dup p.G109Wfs*? (on ENST00000372354; = p.G117Wfs*140 on NM_057090.2) | Frame Shift Ins (INS) | VAF 115/667 reads (17%) | called by mutect2, pindel, varscan2
- ASB18 | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- ASPHD2 | c.907T>C p.C303R | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP6V0A1 | c.1173A>G p.P391= | Splice Region (SNP) | VAF 23/197 reads (12%) | called by muse, mutect2, varscan2
- AXIN2 | c.1915A>G p.S639G | Missense Mutation (SNP) | VAF 160/319 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BEGAIN | c.1661C>G p.P554R | Missense Mutation (SNP) | VAF 255/522 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BEST2 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 216/466 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- BIRC3 | c.294T>A p.S98R | Missense Mutation (SNP) | VAF 198/389 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BPIFB3 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 159/346 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- C11orf68 | c.577C>A p.R193S (on ENST00000530188; = p.R234S on NM_031450.4) | Missense Mutation (SNP) | VAF 197/377 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- C16orf74 | c.229T>C p.*77Rext*37 | Nonstop Mutation (SNP) | VAF 71/288 reads (25%) | called by muse, mutect2, varscan2
- C16orf96 | c.1825A>G p.T609A | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2
- C17orf113 | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 202/402 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD3 | c.1796T>C p.L599S | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CABP1 | c.1019G>T p.G340V (on ENST00000316803 / NM_001033677.1; = p.G137V on NM_004276.5) | Missense Mutation (SNP) | VAF 25/357 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CACNB2 | c.172A>C p.S58R (on ENST00000324631 / NM_201596.3; = p.S30R on NM_201571.4) | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- CBX4 | c.1419A>G p.I473M | Missense Mutation (SNP) | VAF 41/644 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2
- CCDC102A | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC88B | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- CD19 | c.945A>G p.R315= | Splice Region (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2, varscan2
- CDC14A | c.626dup p.E210* | Frame Shift Ins (INS) | VAF 63/173 reads (36%) | called by mutect2, pindel, varscan2
- CDH23 | c.5699T>C p.F1900S | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH24 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 213/404 reads (53%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR1 | c.6356T>C p.L2119P | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHD9 | c.4854dup p.H1619Tfs*7 | Frame Shift Ins (INS) | VAF 30/298 reads (10%) | called by mutect2, pindel
- CHST12 | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 179/390 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CHUK | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CIC | c.65dup p.A23Sfs*16 | Frame Shift Ins (INS) | VAF 50/429 reads (12%) | called by mutect2, varscan2
- CLCN2 | c.1080G>T p.M360I | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CLCN7 | c.2302C>T p.H768Y | Missense Mutation (SNP) | VAF 21/518 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); called by muse, mutect2
- CLDN19 | c.368dup p.A124Sfs*37 | Frame Shift Ins (INS) | VAF 47/358 reads (13%) | called by mutect2, pindel, varscan2
- CNN1 | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- COL16A1 | c.4573A>G p.I1525V | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A3 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSF2RB | c.852A>G p.A284= | Splice Region (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- CTC1 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTNS | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX23 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDX39A | c.637_638insCCCCTCCTT p.I213delinsTPPF | In Frame Ins (INS) | VAF 68/180 reads (38%) | called by mutect2, pindel, varscan2
- DDX3X | c.1448T>G p.L483R (on ENST00000399959; = p.L484R on NM_001356.5) | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIO3 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 40/560 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH10 | c.5773T>C p.Y1925H (on ENST00000409039; = p.Y1864H on NM_207437.3) | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2
- DNAH10 | c.8935T>C p.Y2979H (on ENST00000409039; = p.Y2918H on NM_207437.3) | Missense Mutation (SNP) | VAF 52/491 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- DNAH10 | c.9346A>G p.K3116E (on ENST00000409039; = p.K3055E on NM_207437.3) | Missense Mutation (SNP) | VAF 21/520 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.017); called by muse, mutect2
- DNASE1L1 | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOT1L | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 188/371 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOT1L | c.3492dup p.V1165Rfs*28 | Frame Shift Ins (INS) | VAF 196/547 reads (36%) | called by pindel, varscan2
- DPF2 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP11 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUXB | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1H1 | c.10090A>G p.R3364G | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DYNC2I1 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHBP1L1 | c.3304T>C p.F1102L | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ENPP1 | c.1670A>G p.H557R | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FA2H | c.716A>G p.H239R | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM102A | c.1075T>C p.S359P (on ENST00000373095 / NM_001035254.3; = p.S217P on NM_203305.2) | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FAM114A1 | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, varscan2
- FAM187B | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- FNDC11 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 42/502 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.962); called by muse, mutect2
- FREM1 | c.6003dup p.R2002Qfs*23 | Frame Shift Ins (INS) | VAF 22/180 reads (12%) | called by mutect2, pindel, varscan2
- FSCN2 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 51/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCNA | c.917A>G p.D306G | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPANK1 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 328/638 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- GRIN3B | c.2611T>C p.Y871H | Missense Mutation (SNP) | VAF 51/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRK7 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 217/462 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HAX1 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- HCFC1 | c.223A>T p.R75W | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HIVEP2 | c.6364G>A p.D2122N | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2
- HNRNPL | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 25/742 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.153); called by muse, mutect2
- HOMER3 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 43/461 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- HPS4 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HSPA2 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 145/286 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HSPBP1 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 169/369 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFT140 | c.3746T>C p.M1249T | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IGHV7-81 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL13RA1 | c.425T>C p.M142T | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL13RA1 | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- INTS1 | c.3668T>C p.M1223T | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2
- KDM2B | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 106/225 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KDM5A | c.23dup p.Y9Lfs*15 | Frame Shift Ins (INS) | VAF 94/268 reads (35%) | called by pindel, varscan2
- KHNYN | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- KLF2 | c.711dup p.A238Rfs*62 | Frame Shift Ins (INS) | VAF 56/397 reads (14%) | called by mutect2, varscan2
- KLHL24 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 130/293 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2E | c.4676dup p.N1559Kfs*12 | Frame Shift Ins (INS) | VAF 74/436 reads (17%) | called by mutect2, pindel, varscan2
- LBHD2 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 190/393 reads (48%) | SIFT tolerated (0.38); called by muse, mutect2
- LCORL | c.3745A>G p.R1249G | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIMCH1 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.711); called by muse, mutect2
- LMF1 | c.1303A>G p.M435V | Missense Mutation (SNP) | VAF 48/414 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPO | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LPO | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- LRRC37A2 | c.3878A>G p.K1293R | Missense Mutation (SNP) | VAF 46/1312 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- LRRTM3 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- MAN1C1 | c.1004T>C p.L335S | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.525); called by muse, mutect2
- MAST4 | c.5560A>G p.T1854A (on ENST00000403625 / NM_001164664.2; = p.T1665A on NM_015183.3) | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MC3R | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- MED13 | c.5665A>G p.S1889G | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2
- MLLT6 | c.1130dup p.S378Ffs*15 | Frame Shift Ins (INS) | VAF 48/479 reads (10%) | called by mutect2, pindel, varscan2
- MRPS18B | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH5 | c.1916A>G p.E639G | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- MSLN | c.1256T>C p.V419A (on ENST00000382862 / NM_013404.4; = p.V411A on NM_005823.6) | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MYCBP2 | c.13735dup p.C4579Lfs*2 (on ENST00000357337; = p.C4617Lfs*2 on NM_015057.5) | Frame Shift Ins (INS) | VAF 131/332 reads (39%) | called by mutect2, pindel, varscan2
- MYO1C | c.1799T>C p.V600A (on ENST00000648651 / NM_001080779.2; = p.V565A on NM_033375.5) | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- NACAD | c.442A>G p.S148G | Missense Mutation (SNP) | VAF 61/411 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDST1 | c.1406A>G p.Y469C | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NDUFB3 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- NEDD4 | c.2171T>C p.L724P (on ENST00000508342 / NM_001284338.1; = p.L305P on NM_006154.4) | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2
- NF1 | c.661dup p.W221Lfs*10 | Frame Shift Ins (INS) | VAF 36/239 reads (15%) | called by mutect2, pindel, varscan2
- NIBAN3 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NLRP5 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NOS1AP | c.1369T>C p.F457L | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- NRBP1 | c.1570A>G p.S524G | Missense Mutation (SNP) | VAF 20/379 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- NRXN2 | c.4156A>G p.R1386G | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2
- NSUN5 | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, varscan2
- OPN1LW | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- OR2A14 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2
- OR2W3 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 34/457 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.41); called by muse, mutect2
- PAK6 | c.1051T>C p.S351P | Missense Mutation (SNP) | VAF 227/495 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PARD3 | c.3211A>G p.R1071G | Missense Mutation (SNP) | VAF 137/280 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PATZ1 | c.1963C>T p.L655F | Missense Mutation (SNP) | VAF 70/479 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAX5 | c.1174T>C p.*392Rext*111 | Nonstop Mutation (SNP) | VAF 227/492 reads (46%) | called by muse, mutect2, varscan2
- PCDHA4 | c.2194T>C p.C732R | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHGA9 | c.2338A>G p.I780V | Missense Mutation (SNP) | VAF 185/396 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCSK5 | c.2773A>G p.K925E | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PFKFB2 | c.1475T>C p.L492P | Missense Mutation (SNP) | VAF 175/358 reads (49%) | PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PFKP | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PGGHG | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 37/507 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2
- PHLPP1 | c.3197A>G p.D1066G | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIBF1 | c.1472A>T p.Y491F | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- PIEZO1 | c.1697A>G p.Q566R | Missense Mutation (SNP) | VAF 52/512 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- PIP4K2B | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 60/554 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PLEC | c.12074T>C p.L4025P (on ENST00000322810 / NM_201380.4; = p.L3915P on NM_000445.5) | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLEC | c.1487dup p.G497Wfs*30 (on ENST00000322810 / NM_201380.4; = p.G387Wfs*30 on NM_000445.5) | Frame Shift Ins (INS) | VAF 40/396 reads (10%) | called by mutect2, pindel
- PLVAP | c.1108A>G p.R370G | Missense Mutation (SNP) | VAF 168/307 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PLXND1 | c.62dup p.P22Afs*410 | Frame Shift Ins (INS) | VAF 72/578 reads (12%) | called by mutect2, pindel, varscan2
- PMPCA | c.58T>A p.C20S | Missense Mutation (SNP) | VAF 53/468 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNPLA2 | c.250dup p.L84Pfs*22 | Frame Shift Ins (INS) | VAF 40/374 reads (11%) | called by mutect2, pindel, varscan2
- PRCP | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PREX2 | c.3572T>A p.L1191H | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); called by muse, mutect2
- PRRC2A | c.2762G>T p.R921L | Missense Mutation (SNP) | VAF 73/720 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PTDSS2 | c.1052T>G p.L351R | Missense Mutation (SNP) | VAF 59/484 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PTK2B | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 31/450 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- RABGAP1 | c.1402A>G p.T468A | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- RAPGEF6 | c.3863T>C p.L1288P | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- RNF214 | c.368G>C p.S123T | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.011); called by muse, mutect2
- RNF43 | c.2176T>C p.W726R | Missense Mutation (SNP) | VAF 70/486 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RORC | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPE65 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 149/307 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- S100A14 | c.32A>G p.D11G | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD9L | c.2242A>G p.T748A | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- SCAF11 | c.1829dup p.L611Vfs*5 | Frame Shift Ins (INS) | VAF 122/312 reads (39%) | called by mutect2, pindel, varscan2
- SETD2 | c.4953dup p.T1652Yfs*14 | Frame Shift Ins (INS) | VAF 23/246 reads (9%) | called by pindel, varscan2
- SETD2 | c.4709T>C p.L1570P | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3A2 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 106/251 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SGTA | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 147/278 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SIDT2 | c.1562T>C p.L521P | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- SIGLECL1 | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); called by muse, mutect2
- SLC22A11 | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC22A12 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 182/375 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO1B1 | c.1720T>C p.F574L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2
- SLX4 | c.4121T>C p.L1374P | Missense Mutation (SNP) | VAF 227/468 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA1 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORL1 | c.2823G>C p.E941D | Missense Mutation (SNP) | VAF 136/290 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPNS1 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 35/566 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- SRPRA | c.514dup p.A172Gfs*7 | Frame Shift Ins (INS) | VAF 19/164 reads (12%) | called by mutect2, pindel, varscan2
- STAB2 | c.4814A>C p.K1605T | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- STRN4 | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 36/527 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.244); called by muse, mutect2
- SUZ12 | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- SYNE3 | c.1657T>C p.F553L | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYT17 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCF20 | c.701A>T p.H234L | Missense Mutation (SNP) | VAF 64/531 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- TDRD7 | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TEX15 | c.5504T>A p.L1835* (on ENST00000256246; = p.L2218* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 126/294 reads (43%) | called by muse, mutect2, varscan2
- TLR5 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 57/358 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM216 | c.231T>C p.G77= (on ENST00000515837 / NM_001173990.3; = p.G16= on NM_016499.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 48/188 reads (26%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.1087T>C p.S363P (on ENST00000648592; = p.S329P on NM_182973.2) | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNFRSF4 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 24/515 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TOP2A | c.1792T>C p.W598R | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TOR4A | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 56/551 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TRAV2 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- TRERF1 | c.2058G>T p.Q686H | Missense Mutation (SNP) | VAF 59/558 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TRIM50 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2
- TRIOBP | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 228/417 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- TRPV3 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TSC2 | c.2414T>C p.V805A | Missense Mutation (SNP) | VAF 45/453 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TTN | c.48944T>C p.I16315T (on ENST00000591111; = p.I8891T on NM_003319.4) | Missense Mutation (SNP) | VAF 5/130 reads (4%) | PolyPhen possibly damaging (0.88); called by muse, mutect2
- TYRO3 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UAP1L1 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- UBAC1 | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 177/394 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBE2O | c.3250T>C p.F1084L | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UMODL1 | c.146A>T p.E49V | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- UPK3A | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- USP34 | c.5333dup p.D1779Gfs*3 | Frame Shift Ins (INS) | VAF 81/246 reads (33%) | called by mutect2, pindel, varscan2
- USP42 | c.1784G>C p.G595A | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- VARS1 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 247/463 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- VDR | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- VN1R1 | c.935T>C p.L312S | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- VWA5B2 | c.1972T>C p.S658P | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- WDR81 | c.2714T>C p.L905P | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- YY1 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZC3H18 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 210/430 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ZC3H18 | c.1769G>T p.S590I | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZC3H18 | c.2096G>A p.S699N | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF175 | c.1927T>C p.Y643H | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF324 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 86/543 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ZNF337 | c.1853A>G p.H618R | Missense Mutation (SNP) | VAF 135/260 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF408 | c.1997A>G p.E666G | Missense Mutation (SNP) | VAF 187/400 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF609 | c.808A>G p.N270D | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- ZNF782 | c.914G>T p.R305I | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.193); called by muse, mutect2
- ZNF839 | c.799dup p.A267Gfs*23 (on ENST00000558850 / NM_001267827.1; = p.A383Gfs*23 on NM_018335.5) | Frame Shift Ins (INS) | VAF 56/362 reads (15%) | called by mutect2, pindel, varscan2
- ZSWIM2 | c.1132A>G p.K378E | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- AARS2 | c.2478A>G p.R826= | Silent (SNP) | VAF 25/196 reads (13%) | called by muse, mutect2, varscan2
- ABCA4 | c.6462T>C p.I2154= | Silent (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- ACTR1B | c.261A>G p.E87= | Silent (SNP) | VAF 140/303 reads (46%) | called by muse, mutect2, varscan2
- APOL2 | c.729G>A p.P243= | Silent (SNP) | VAF 14/429 reads (3%) | catalogued as rs996251871; called by muse, mutect2
- ATG101 | c.642C>T p.D214= | Silent (SNP) | VAF 87/196 reads (44%) | called by muse, mutect2, varscan2
- ATRIP | c.2280A>G p.R760= (on ENST00000320211 / NM_130384.3; = p.R733= on NM_032166.4) | Silent (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- BCAR3 | c.1851G>A p.T617= | Silent (SNP) | VAF 40/266 reads (15%) | catalogued as rs138631396; called by muse, mutect2, varscan2
- C8orf76 | c.387A>G p.L129= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- CD109 | c.3888T>C p.H1296= | Silent (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- CD300A | c.321A>G p.T107= | Silent (SNP) | VAF 20/444 reads (5%) | called by muse, mutect2
- CEP152 | c.2622A>G p.A874= | Silent (SNP) | VAF 39/231 reads (17%) | catalogued as COSV104395361; called by muse, mutect2, varscan2
- CFAP92 | c.519T>C p.T173= | Silent (SNP) | VAF 141/283 reads (50%) | called by muse, mutect2, varscan2
- CFAP94 | c.963A>G p.Q321= (on ENST00000320267 / NM_001352064.2; = p.Q327= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/203 reads (42%) | called by muse, mutect2, varscan2
- CHADL | c.183T>C p.P61= | Silent (SNP) | VAF 119/232 reads (51%) | called by muse, mutect2, varscan2
- CHD4 | c.1437T>C p.R479= (on ENST00000357008 / NM_001363606.2; = p.R492= on NM_001273.5) | Silent (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- CHKA | c.1080T>C p.P360= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as rs753094302, COSV55839986; called by muse, mutect2
- CILP2 | c.3117C>T p.P1039= | Silent (SNP) | VAF 66/423 reads (16%) | catalogued as rs745826472; called by muse, mutect2, varscan2
- CPEB4 | c.1680T>C p.P560= | Silent (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- CRAMP1 | c.966T>C p.P322= | Silent (SNP) | VAF 52/356 reads (15%) | called by muse, mutect2, varscan2
- CRYBG2 | c.807A>C p.T269= | Silent (SNP) | VAF 68/425 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.10479T>C p.D3493= (on ENST00000297405 / NM_001363185.1; = p.D3324= on NM_052900.3) | Silent (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- DBF4B | c.1842A>G p.S614= | Silent (SNP) | VAF 35/184 reads (19%) | catalogued as rs1334680637; called by muse, mutect2, varscan2
- DNAH3 | c.8214T>C p.D2738= | Silent (SNP) | VAF 38/355 reads (11%) | called by muse, mutect2, varscan2
- DPH2 | c.372T>C p.L124= | Silent (SNP) | VAF 179/336 reads (53%) | catalogued as rs746332957; called by muse, mutect2, varscan2
- EGFL7 | c.519T>C p.G173= | Silent (SNP) | VAF 40/370 reads (11%) | called by muse, varscan2
- EPHA3 | c.2010A>G p.E670= | Silent (SNP) | VAF 43/376 reads (11%) | called by muse, mutect2, varscan2
- ESRRA | c.165T>C p.D55= | Silent (SNP) | VAF 80/479 reads (17%) | called by muse, mutect2, varscan2
- ETNPPL | c.717A>T p.A239= | Silent (SNP) | VAF 35/238 reads (15%) | called by muse, mutect2, varscan2
- FAM184B | c.3177T>C p.S1059= | Silent (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- FILIP1 | c.2196C>T p.H732= | Silent (SNP) | VAF 29/262 reads (11%) | catalogued as rs754618124, COSV52723104; called by muse, mutect2, varscan2
- FRS3 | c.394C>A p.R132= | Silent (SNP) | VAF 15/269 reads (6%) | called by muse, mutect2
- GART | c.1755A>G p.L585= | Silent (SNP) | VAF 39/296 reads (13%) | called by muse, mutect2, varscan2
- GNAZ | c.132A>G p.S44= | Silent (SNP) | VAF 184/380 reads (48%) | called by muse, varscan2
- GPCPD1 | c.2001T>C p.D667= | Silent (SNP) | VAF 17/215 reads (8%) | called by muse, mutect2
- GPR19 | c.48T>C p.I16= | Silent (SNP) | VAF 16/263 reads (6%) | called by muse, mutect2
- HDAC4 | c.1173C>T p.T391= | Silent (SNP) | VAF 88/569 reads (15%) | catalogued as rs1317966895; called by muse, mutect2, varscan2
- HEATR4 | c.2832A>G p.E944= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- HSPA4 | c.1281T>G p.P427= | Silent (SNP) | VAF 30/219 reads (14%) | called by muse, mutect2, varscan2
- ICAM1 | c.240A>G p.E80= | Silent (SNP) | VAF 16/402 reads (4%) | catalogued as rs1390690093; called by muse, mutect2
- ITIH2 | c.408T>C p.T136= | Silent (SNP) | VAF 166/318 reads (52%) | catalogued as COSV64434052; called by muse, mutect2, varscan2
- KHNYN | c.525T>C p.H175= | Silent (SNP) | VAF 39/498 reads (8%) | called by muse, mutect2
- KIF15 | c.918T>C p.G306= | Silent (SNP) | VAF 89/247 reads (36%) | called by muse, mutect2, varscan2
- LMBRD2 | c.1371A>G p.V457= | Silent (SNP) | VAF 146/287 reads (51%) | called by muse, mutect2, varscan2
- LRP2 | c.10461A>G p.K3487= | Silent (SNP) | VAF 167/371 reads (45%) | catalogued as COSV99786134; called by muse, mutect2
- LRRIQ1 | c.303T>C p.T101= | Silent (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- MAML2 | c.237T>C p.L79= | Silent (SNP) | VAF 93/557 reads (17%) | called by muse, mutect2, varscan2
- MAP4K5 | c.2049G>A p.Q683= | Silent (SNP) | VAF 51/349 reads (15%) | called by muse, mutect2, varscan2
- MLLT10 | c.555C>A p.A185= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- MST1R | c.2190T>C p.S730= | Silent (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- MYO15B | c.6963A>G p.L2321= | Silent (SNP) | VAF 59/263 reads (22%) | catalogued as rs1265714981; called by muse, mutect2, varscan2
- MYOT | c.1485T>C p.S495= | Silent (SNP) | VAF 12/248 reads (5%) | catalogued as rs1237257657; called by muse, mutect2
- NASP | c.1125T>C p.P375= | Silent (SNP) | VAF 69/336 reads (21%) | called by muse, mutect2, varscan2
- NCL | c.603T>C p.D201= | Silent (SNP) | VAF 27/288 reads (9%) | catalogued as rs371218401; called by muse, mutect2
- NFRKB | c.1953T>C p.H651= (on ENST00000446488 / NM_001143835.2; = p.H676= on NM_006165.3) | Silent (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- OGN | c.876A>G p.L292= | Silent (SNP) | VAF 35/201 reads (17%) | called by muse, mutect2, varscan2
- PDZD4 | c.774A>G p.E258= | Silent (SNP) | VAF 190/191 reads (99%) | called by muse, mutect2, varscan2
- PIGC | c.222T>C p.Y74= | Silent (SNP) | VAF 38/308 reads (12%) | called by muse, mutect2, varscan2
- PIK3C2B | c.2482T>C p.L828= | Silent (SNP) | VAF 44/301 reads (15%) | catalogued as rs754401350; called by muse, mutect2, varscan2
- PLXNB1 | c.2916T>C p.P972= | Silent (SNP) | VAF 50/317 reads (16%) | called by muse, mutect2, varscan2
- PNPO | c.144T>C p.F48= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, varscan2
- PRELID3B | c.207T>C p.I69= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- PRRC2C | c.567A>G p.S189= (on ENST00000367742; = p.S187= on NM_015172.4) | Silent (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- PSAPL1 | c.408G>A p.A136= | Silent (SNP) | VAF 232/532 reads (44%) | catalogued as rs767261815, COSV100040616; called by muse, mutect2
- PTBP3 | c.1605T>C p.H535= | Silent (SNP) | VAF 21/302 reads (7%) | called by muse, mutect2
- PWWP3A | c.1254T>C p.H418= (on ENST00000627377; = p.H417= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 36/271 reads (13%) | called by muse, mutect2, varscan2
- PYCR1 | c.177G>A p.T59= | Silent (SNP) | VAF 170/356 reads (48%) | catalogued as rs1030168942, COSV57999070; called by muse, mutect2, varscan2
- PYCR3 | c.354A>G p.T118= | Silent (SNP) | VAF 43/382 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.1248A>G p.T416= (on ENST00000389212; = p.T374= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/241 reads (44%) | called by muse, mutect2, varscan2
- RILPL1 | c.798T>C p.P266= | Silent (SNP) | VAF 33/235 reads (14%) | called by muse, mutect2, varscan2
- RIN1 | c.888C>G p.R296= | Silent (SNP) | VAF 56/630 reads (9%) | catalogued as rs764041983; called by muse, mutect2
- RMDN3 | c.663A>G p.S221= | Silent (SNP) | VAF 23/486 reads (5%) | called by muse, mutect2
- ROBO2 | c.277T>C p.L93= | Silent (SNP) | VAF 32/382 reads (8%) | called by muse, mutect2
- RPUSD2 | c.996A>G p.V332= | Silent (SNP) | VAF 52/336 reads (15%) | called by muse, mutect2, varscan2
- RTN4R | c.951T>C p.H317= | Silent (SNP) | VAF 216/437 reads (49%) | called by muse, mutect2, varscan2
- SCNN1B | c.1668G>A p.V556= | Silent (SNP) | VAF 53/464 reads (11%) | catalogued as COSV56309253; called by muse, mutect2, varscan2
- SERPINB4 | c.402T>A p.T134= | Silent (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- SKIDA1 | c.2673C>G p.G891= | Silent (SNP) | VAF 26/266 reads (10%) | catalogued as COSV71610903, COSV71611106; called by muse, mutect2
- SLC15A4 | c.1242C>T p.C414= | Silent (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- SLC22A11 | c.708T>C p.C236= | Silent (SNP) | VAF 48/528 reads (9%) | called by muse, mutect2
- SLC25A13 | c.984G>T p.S328= | Silent (SNP) | VAF 45/361 reads (12%) | called by muse, mutect2, varscan2
- SLC2A6 | c.126C>A p.T42= | Silent (SNP) | VAF 173/311 reads (56%) | called by muse, mutect2, varscan2
- SLC38A3 | c.1083G>A p.P361= | Silent (SNP) | VAF 33/393 reads (8%) | catalogued as rs775289542, COSV68844031; called by muse, mutect2
- SLC5A9 | c.1950A>G p.T650= | Silent (SNP) | VAF 21/508 reads (4%) | called by muse, mutect2
- SON | c.2076T>C p.P692= | Silent (SNP) | VAF 20/322 reads (6%) | catalogued as COSV99278278; called by muse, mutect2
- STARD5 | c.171A>G p.V57= | Silent (SNP) | VAF 36/280 reads (13%) | called by muse, mutect2, varscan2
- STOX2 | c.222G>T p.A74= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- SUCO | c.240T>C p.I80= | Silent (SNP) | VAF 104/211 reads (49%) | called by muse, mutect2, varscan2
- SUPT5H | c.2604A>G p.P868= | Silent (SNP) | VAF 67/738 reads (9%) | called by muse, mutect2
- TCOF1 | c.3483A>G p.E1161= (on ENST00000377797 / NM_001135243.1; = p.E1084= on NM_000356.4) | Silent (SNP) | VAF 50/271 reads (18%) | called by muse, mutect2, varscan2
- THAP11 | c.672T>C p.P224= | Silent (SNP) | VAF 32/400 reads (8%) | called by muse, mutect2
- TMEM126A | c.561A>G p.L187= | Silent (SNP) | VAF 23/250 reads (9%) | called by muse, mutect2
- TRMT5 | c.198T>C p.H66= | Silent (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- TSPOAP1 | c.2451A>G p.Q817= | Silent (SNP) | VAF 84/511 reads (16%) | catalogued as COSV52112730; called by muse, mutect2, varscan2
- TUBGCP6 | c.796T>C p.L266= | Silent (SNP) | VAF 168/355 reads (47%) | called by muse, mutect2, varscan2
- VWDE | c.2169A>G p.L723= | Silent (SNP) | VAF 44/285 reads (15%) | catalogued as rs1457585790; called by muse, mutect2, varscan2
- XIAP | c.612T>C p.G204= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as rs1305469878; called by muse, mutect2, varscan2
- XIRP2 | c.9759A>G p.Q3253= (on ENST00000628543; = p.Q3428= on NM_152381.6) | Silent (SNP) | VAF 35/352 reads (10%) | called by muse, mutect2, varscan2
- ZFHX2 | c.3369T>G p.P1123= | Silent (SNP) | VAF 40/309 reads (13%) | called by mutect2, varscan2
- ZMYM2 | c.2643A>G p.E881= | Silent (SNP) | VAF 23/222 reads (10%) | called by muse, mutect2, varscan2
- ZNF528 | c.1113T>C p.H371= | Silent (SNP) | VAF 50/362 reads (14%) | called by muse, mutect2, varscan2
- ZNF559 | c.516T>C p.H172= | Silent (SNP) | VAF 37/427 reads (9%) | called by muse, mutect2
- ZNF74 | c.1680A>G p.K560= | Silent (SNP) | VAF 41/375 reads (11%) | called by muse, mutect2, varscan2
- CELF2 | c.1076-349T>C | Intron (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- CHD2 | c.62+41G>T | Intron (SNP) | VAF 34/312 reads (11%) | catalogued as rs996619975; called by mutect2, varscan2
- CYP2G1P | n.1210C>T | RNA (SNP) | VAF 42/306 reads (14%) | catalogued as rs772811510; called by muse, mutect2, varscan2
- DCST1 | c.1869+852T>C | Intron (SNP) | VAF 37/238 reads (16%) | called by muse, mutect2, varscan2
- FAAP100 | c.*369A>G | 3'UTR (SNP) | VAF 40/322 reads (12%) | called by muse, mutect2, varscan2
- FLAD1 | c.373-23T>G | Intron (SNP) | VAF 51/331 reads (15%) | called by muse, mutect2, varscan2
- IGHA1 | chr14:105704495 T>C | 3'Flank (SNP) | VAF 130/322 reads (40%) | called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162681 ins TCC | 3'Flank (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- KCNQ1 | c.1393+27023A>G | Intron (SNP) | VAF 112/242 reads (46%) | catalogued as rs1300392967; called by muse, mutect2, varscan2
- LCN8 | c.93+525A>G | Intron (SNP) | VAF 19/447 reads (4%) | catalogued as COSV60210331; called by muse, mutect2
- MADD | c.4722+52A>G | Intron (SNP) | VAF 54/393 reads (14%) | catalogued as rs751845510; called by muse, mutect2, varscan2
- SGIP1 | c.99+999dup | Intron (INS) | VAF 37/229 reads (16%) | catalogued as rs745636084; called by mutect2, varscan2
- TRIM46 | c.1588+544C>A | Intron (SNP) | VAF 10/233 reads (4%) | called by muse, mutect2
- UNC13B | c.1168-14728A>G | Intron (SNP) | VAF 114/286 reads (40%) | called by muse, mutect2
